Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A963, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A963-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: max 3.8 cm

Diagnosis:

Type A/B Thymoma

pT2

Masaoka: II.1

Immunohistochemistry

epithelial cells positive for: CK5/6, CK19

epithelial cells negative for: CK20

CD1a-positive T-lymphocytes

ICD-O-3
Thymoma, Type AB,
malignant 8582/3
Site: Anterior mediastinum
C38.1
Jx 4/7/14

Source: NCI Genomic Data Commons file 851c2d0e-c39e-4924-949f-bceac8ed3e0c (TCGA-ZB-A963.9A6AB32E-8615-4C5D-B714-2FA44372BCCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).